TCGA case TCGA-49-4514 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Johns Hopkins. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b87a5d92-4c09-48fe-bb08-b3c89a7c892e

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 79 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 79.1 years (28,908 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,314 days (3.6 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,700.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 65.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-49-4514-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.4; Intermediate dimension: 0.8; Shortest dimension: 0.4.
  Slide TCGA-49-4514-01A-01-BS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 50; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-49-4514-01A-02-BS2: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-49-4514-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-49-4514-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 0.6; Shortest dimension: 0.6.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Papillary Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Upper.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,700 days; disease-specific survival: no event (censored), 1,700 days; disease-free interval: no event (censored), 1,700 days; progression-free interval: no event (censored), 1,700 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-49-4514-01A-21D-1854-01): tumor purity 0.35, ploidy 1.79, whole-genome doublings 0.
